Somatic mutation profile of tumor specimen TCGA-DC-5337-01A (aliquot TCGA-DC-5337-01A-01D-1657-10) from TCGA case TCGA-DC-5337, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 69.0 years (25,202 days).
Specimen TCGA-DC-5337-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77b8b70d-c69b-44fd-87d3-396e9fe00c69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DC-5337-10A (Blood Derived Normal), aliquot TCGA-DC-5337-10A-01D-1657-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7d31102-07d6-49ce-9ee9-b9457447a2f2

The open-access MAF lists 118 somatic variants for this specimen: 86 protein-altering or splice-affecting, 32 silent.
By variant classification: Missense Mutation 70, Silent 32, Splice Site 4, Frame Shift Ins 4, Nonsense Mutation 3, Splice Region 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 44/122 reads (36%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.5344G>A p.G1782R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374718902, CM960407; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.1864C>T p.R622W (on ENST00000359125 / NM_172107.4; = p.R594W on NM_004518.6) | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs772405187, COSV60541032; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 8/21 reads (38%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 72/197 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.5920C>T p.R1974W | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs779733902, COSV62095985; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS3 | c.948C>T p.S316= | Splice Region (SNP) | VAF 14/213 reads (7%) | catalogued as COSV99710126; called by muse, mutect2
- AK1 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761271981, COSV99802310; called by muse, mutect2, varscan2
- AKAP6 | c.6332C>T p.S2111L | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773070431, COSV55206503; called by muse, mutect2, varscan2
- AMBRA1 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as COSV54049544; called by muse, mutect2, varscan2
- ANKDD1A | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs761588607, COSV60352973; called by muse, mutect2, varscan2
- ASB12 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs765670083, COSV62856171, COSV62857708; called by muse, mutect2, varscan2
- BAIAP3 | c.2473G>T p.A825S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.074); catalogued as COSV50103631; called by muse, mutect2
- CD8A | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52157656; called by muse, mutect2, varscan2
- CPNE4 | c.888C>A p.F296L | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV101456567; called by muse, varscan2
- CSMD3 | c.10963del p.R3655Gfs*46 (on ENST00000297405 / NM_001363185.1; = p.R3486Gfs*46 on NM_052900.3) | Frame Shift Del (DEL) | VAF 25/88 reads (28%) | catalogued as COSV52106600; called by mutect2, pindel, varscan2
- CUL7 | c.4441-1G>T p.X1481_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99537798; called by muse, mutect2, varscan2
- DCBLD1 | c.976+1G>T p.X326_splice | Splice Site (SNP) | VAF 18/53 reads (34%) | catalogued as COSV99757076; called by muse, mutect2, varscan2
- DDX23 | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57282278; called by muse, mutect2
- DDX23 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV57282287; called by muse, mutect2, varscan2
- DOP1B | c.731G>T p.R244I | Missense Mutation (SNP) | VAF 155/433 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67692332; called by muse, mutect2, varscan2
- DSC1 | c.2300G>A p.G767D | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs781031026, COSV57142532; called by muse, mutect2, varscan2
- EPHA4 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV56027767; called by muse, mutect2, varscan2
- FAM120A | c.2362G>A p.G788R | Missense Mutation (SNP) | VAF 114/283 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52901817; called by muse, mutect2, varscan2
- FREM1 | c.3301G>A p.A1101T | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.115); catalogued as rs369918312; called by muse, mutect2, varscan2
- FYCO1 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99945122; called by muse, mutect2, varscan2
- GALNT17 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775779137, COSV61150179, COSV61154998; called by muse, mutect2, varscan2
- GDF15 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.014); catalogued as COSV53250704, COSV99416005; called by muse, mutect2, varscan2
- GYS2 | c.1703C>T p.T568I | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99679408; called by muse, mutect2, varscan2
- HS3ST3A1 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1018119566, COSV52373160; called by muse, mutect2, varscan2
- IPO8 | c.1069dup p.S357Ffs*6 | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | catalogued as rs1438426784; called by mutect2, pindel, varscan2
- IPP | c.554A>T p.K185I | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV63431975; called by muse, mutect2, varscan2
- IQCH | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs765558699, COSV60056889; called by muse, mutect2, varscan2
- ITGA5 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.224); catalogued as rs1294078639, COSV53215090, COSV53219955; called by muse, mutect2, varscan2
- KIF2B | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs1479427821, COSV52127121; called by muse, mutect2, varscan2
- LRRC15 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs764147493, COSV61649595; called by muse, mutect2, varscan2
- MAP1S | c.2909G>A p.R970H | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs757937252, COSV60721902; called by muse, mutect2, varscan2
- MCEE | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs377624743; called by muse, mutect2, varscan2
- MED12 | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 79/103 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61333771, COSV61336783; called by muse, mutect2, varscan2
- MMP11 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs376901794; called by muse, mutect2, varscan2
- MUC2 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs372858384; called by muse, mutect2
- MXRA5 | c.6460C>T p.R2154W | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54226273; called by muse, varscan2
- MYO18A | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs373037295; called by muse, mutect2, varscan2
- NOXA1 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs145080773; called by muse, mutect2, varscan2
- OBSCN | c.19114G>A p.G6372R | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as rs780775022, COSV52793178; called by muse, mutect2, varscan2
- OLFM1 | c.799G>A p.G267S (on ENST00000371793 / NM_001282611.2; = p.G249S on NM_014279.5) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.082); catalogued as rs772311640, COSV53276745; called by muse, mutect2, varscan2
- OR1G1 | c.457G>C p.A153P | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.5); catalogued as COSV100187493; called by muse, mutect2, varscan2
- PARP4 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 131/369 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960811; called by muse, mutect2, varscan2
- PCDHGA3 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.044); catalogued as COSV53891908; called by muse, mutect2, varscan2
- PCDHGA5 | c.1868C>T p.T623M | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs187196267; called by muse, mutect2, varscan2
- PCDHGA8 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.02); catalogued as COSV53894985; called by muse, mutect2, varscan2
- PCDHGB3 | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1158442459, COSV99530214; called by muse, mutect2
- PCNX1 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs371108639, COSV53089653; called by muse, mutect2, varscan2
- PCYT1B | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63264169; called by muse, mutect2, varscan2
- PHIP | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1029734967, COSV51501905; called by muse, mutect2, varscan2
- PITPNM3 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752331730, COSV52593394; called by muse, mutect2, varscan2
- PLK1 | c.1242G>A p.W414* | Nonsense Mutation (SNP) | VAF 66/169 reads (39%) | catalogued as COSV99890535; called by muse, mutect2, varscan2
- POLR3B | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99942988; called by muse, mutect2, varscan2
- PPP4R1 | c.2269C>T p.R757W (on ENST00000400556 / NM_001042388.3; = p.R740W on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs867602643, COSV53280688; called by muse, mutect2, varscan2
- PTPRD | c.4187G>A p.R1396Q | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781289256, COSV61931771; called by muse, mutect2, varscan2
- RBBP7 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 200/237 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58112570; called by muse, mutect2, varscan2
- RFX2 | c.1984G>A p.G662R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs753667887, COSV57942961; called by muse, mutect2, varscan2
- RIMS1 | c.4591C>T p.R1531C | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1308617795, COSV53436771; called by muse, mutect2, varscan2
- RING1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs746185117, COSV63002318; called by muse, mutect2, varscan2
- RPH3A | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139903605; called by muse, varscan2
- SIDT1 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs772935487, COSV53498863; called by muse, mutect2, varscan2
- SORCS1 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1353842064, COSV53845885, COSV99550213; called by muse, mutect2, varscan2
- SPZ1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs562377054, COSV57062474; called by muse, mutect2, varscan2
- TCERG1 | c.2965C>T p.R989* | Nonsense Mutation (SNP) | VAF 69/199 reads (35%) | catalogued as rs1561711151, COSV57034000, COSV57040065; called by muse, mutect2, varscan2
- TCP11L1 | c.121A>G p.K41E | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as rs754291466, COSV57514218; called by muse, mutect2, varscan2
- TENM1 | c.4842C>A p.S1614R | Missense Mutation (SNP) | VAF 159/187 reads (85%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.482); catalogued as COSV100948975; called by muse, mutect2, varscan2
- TRPM3 | c.2960G>A p.R987H (on ENST00000357533 / NM_001366142.2; = p.R830H on NM_020952.6) | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs1432206553, COSV62586228; called by muse, mutect2, varscan2
- TRPM4 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs755300832, COSV53260668; called by muse, mutect2, varscan2
- TUBB1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 72/108 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs771118227, COSV53886041; called by muse, mutect2, varscan2
- UBR4 | c.11893-1G>T p.X3965_splice | Splice Site (SNP) | VAF 54/91 reads (59%) | catalogued as COSV100920161; called by muse, mutect2, varscan2
- UBTD1 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146047099; called by muse, mutect2, varscan2
- UNC13B | c.3063G>A p.E1021= | Splice Region (SNP) | VAF 16/56 reads (29%) | catalogued as rs759268832, COSV65931711; called by muse, mutect2, varscan2
- USP8 | c.2159C>A p.P720Q | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56162195, COSV56162692, COSV56165591; called by muse, mutect2, varscan2
- YTHDF2 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV65722833; called by muse, mutect2, varscan2
- ZNF607 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs376563408, COSV67696347; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ITGB7 | c.1621_1659del p.G541_Q553del | In Frame Del (DEL) | VAF 38/110 reads (35%) | called by mutect2, pindel
- NBEA | c.3096dup p.V1033Sfs*4 | Frame Shift Ins (INS) | VAF 71/207 reads (34%) | called by mutect2, pindel, varscan2
- RSPH10B2 | c.325_330+11del p.X109_splice | Splice Site (DEL) | VAF 13/50 reads (26%) | called by mutect2, varscan2
- SOX9 | c.818_819dup p.D274Wfs*6 | Frame Shift Ins (INS) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- TEX14 | c.2348_2349del p.E783Vfs*52 (on ENST00000240361 / NM_001201457.2; = p.E777Vfs*52 on NM_031272.5) | Frame Shift Del (DEL) | VAF 68/252 reads (27%) | called by pindel, varscan2
- ANKRD26 | c.4098C>T p.L1366= | Silent (SNP) | VAF 112/332 reads (34%) | catalogued as rs535737907, COSV65774334; called by muse, mutect2, varscan2
- ARL6IP1 | c.537C>A p.I179= | Silent (SNP) | VAF 45/163 reads (28%) | catalogued as COSV58614137; called by muse, mutect2, varscan2
- BSX | c.522C>T p.D174= | Silent (SNP) | VAF 28/231 reads (12%) | catalogued as COSV58005177; called by muse, mutect2
- C17orf49 | c.210A>G p.E70= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV101143278; called by muse, mutect2, varscan2
- CAND1 | c.939C>T p.Y313= | Silent (SNP) | VAF 58/176 reads (33%) | catalogued as rs367644026; called by muse, mutect2, varscan2
- CD93 | c.144G>A p.E48= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs1308002083, COSV55663706; called by muse, mutect2, varscan2
- CNTNAP5 | c.2043C>T p.H681= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as rs1407550870, COSV101443015; called by muse, mutect2, varscan2
- DMRTB1 | c.678C>T p.D226= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs769317497, COSV65112708; called by muse, mutect2, varscan2
- DNAH17 | c.4179C>T p.Y1393= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs200358276; called by muse, mutect2, varscan2
- EEF1D | c.231C>T p.H77= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs370722668, COSV52782877; called by muse, mutect2, varscan2
- ERC2 | c.2554C>T p.L852= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as rs757576854, COSV55605062; called by muse, mutect2, varscan2
- FAT4 | c.13878C>T p.N4626= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs369989432, COSV100630694, COSV58673947; called by muse, mutect2, varscan2
- FHOD3 | c.1860C>T p.N620= (on ENST00000359247 / NM_001281739.3; = p.N637= on NM_025135.5) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs140443288; called by mutect2, varscan2
- GPR45 | c.46C>T p.L16= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as COSV51522953; called by muse, mutect2, varscan2
- HELT | c.243G>A p.A81= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs772210049, COSV100132799; called by muse, mutect2, varscan2
- ITGA11 | c.2355G>A p.E785= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV59875345; called by muse, mutect2, varscan2
- L3MBTL4 | c.1101G>A p.T367= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs541961038, COSV53114835; called by muse, mutect2, varscan2
- LYPD2 | c.330C>T p.L110= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV100820937; called by muse, varscan2
- LYST | c.10758C>T p.C3586= | Silent (SNP) | VAF 33/146 reads (23%) | catalogued as rs145136281, COSV67707269; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MAP1B | c.1119G>A p.K373= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV57094782; called by muse, mutect2, varscan2
- MCM3AP | c.3243G>A p.A1081= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs778113579, COSV52436872, COSV52440125; called by muse, mutect2, varscan2
- NEFM | c.906G>A p.A302= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV55330837; called by muse, mutect2, varscan2
- NOMO3 | c.1467C>T p.T489= | Silent (SNP) | VAF 179/483 reads (37%) | catalogued as rs749544353, COSV53769467; called by muse, mutect2, varscan2
- NRXN1 | c.465C>T p.V155= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs531571569, COSV68004656; called by muse, varscan2
- P4HB | c.399G>A p.T133= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs370423809; called by muse, mutect2, varscan2
- PCDHA3 | c.1542C>T p.S514= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV63539417; called by muse, mutect2, varscan2
- PRKDC | c.7383C>T p.F2461= | Silent (SNP) | VAF 83/234 reads (35%) | catalogued as rs761453930, COSV58044923; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRR23B | c.753G>A p.P251= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs182603479; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2691C>T p.L897= | Silent (SNP) | VAF 66/193 reads (34%) | catalogued as COSV62782533; called by muse, mutect2, varscan2
- SLC7A5 | c.1161C>T p.Y387= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs771516158, COSV99878972; called by muse, mutect2, varscan2
- SLCO3A1 | c.1443C>A p.S481= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV100574887; called by muse, mutect2, varscan2
- SULF1 | c.456C>T p.I152= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs756737948, COSV52691636; called by muse, mutect2
